Somatic mutation profile of tumor specimen TCGA-EE-A3AB-06A (aliquot TCGA-EE-A3AB-06A-11D-A196-08) from TCGA case TCGA-EE-A3AB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 30.3 years (11,054 days).
Specimen TCGA-EE-A3AB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d59d70ee-4ed0-4ba0-a1b1-75fa01f60104.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3AB-10A (Blood Derived Normal), aliquot TCGA-EE-A3AB-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0eb022f-12b5-49a2-a837-d2d27ac3a08d

The open-access MAF lists 786 somatic variants for this specimen: 533 protein-altering or splice-affecting, 234 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 499, Silent 234, Nonsense Mutation 16, Splice Site 12, Intron 7, 5'Flank 4, RNA 3, 3'UTR 3, Frame Shift Ins 2, Splice Region 2, 5'UTR 2, Translation Start Site 2.

Variants (750 of 786; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.2162dup p.S723Ifs*27 | Frame Shift Ins (INS) | VAF 15/38 reads (39%) | catalogued as rs1554294674; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/152 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DICER1 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 126/390 reads (32%) | catalogued as rs886037672, CM135357, COSV58621515; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO9A | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.964); catalogued as COSV61847987; called by muse, mutect2, varscan2
- A2ML1 | c.855+1G>A p.X285_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as rs746496110, COSV55295657; called by mutect2, varscan2
- ABCA6 | c.4476-1G>A p.X1492_splice | Splice Site (SNP) | VAF 76/286 reads (27%) | catalogued as rs776952954, COSV52642340; called by muse, mutect2, varscan2
- ABCB11 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55592838; called by muse, mutect2, varscan2
- ABCF2 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV55185224; called by muse, mutect2, varscan2
- ABCG1 | c.1333G>C p.G445R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59208352; called by muse, mutect2, varscan2
- ABHD10 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV56325833; called by muse, mutect2, varscan2
- ACAN | c.1709A>G p.Y570C | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61365944; called by muse, mutect2, varscan2
- ACP6 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.159); catalogued as COSV65077596; called by muse, mutect2, varscan2
- ACSM5 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100088988, COSV59373519; called by muse, mutect2, varscan2
- ADAD1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99635039; called by muse, mutect2, varscan2
- ADAMTS6 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV58684444; called by muse, mutect2, varscan2
- ADCK2 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 131/217 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99301359; called by muse, mutect2, varscan2
- ADCK2 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 133/218 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99301361; called by muse, mutect2, varscan2
- ADCY1 | c.1667T>C p.V556A | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV52039499; called by muse, mutect2, varscan2
- ADGRE1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99165020; called by muse, varscan2
- ADGRE5 | c.1000C>T p.L334F (on ENST00000242786 / NM_078481.4; = p.L241F on NM_001784.5) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV54413445; called by muse, mutect2, varscan2
- ADNP2 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV51541261; called by muse, mutect2, varscan2
- AFTPH | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV53220449; called by muse, mutect2, varscan2
- AGPAT3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52372755; called by muse, mutect2, varscan2
- AHNAK2 | c.16468C>G p.L5490V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.09); catalogued as COSV60911036, COSV60924087; called by muse, mutect2
- ALDH3A1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99855720; called by muse, mutect2, varscan2
- ALDH3A1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99855722; called by muse, mutect2, varscan2
- ANK3 | c.10745C>T p.T3582I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55072733; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5611C>T p.R1871C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs781653504, COSV51854507, COSV99783667; called by muse, mutect2, varscan2
- ANKRD13C | c.647T>C p.L216S | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV52033589; called by muse, mutect2, varscan2
- ANKS1B | c.3071G>A p.G1024E (on ENST00000547776 / NM_152788.4; = p.G190E on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV59122891; called by muse, mutect2, varscan2
- ANO7 | c.436G>A p.D146N (on ENST00000274979; = p.D91N on NM_001001666.4) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51475930; called by muse, mutect2, varscan2
- ANTXR1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV58018275; called by muse, mutect2, varscan2
- APBB1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV54973951; called by muse, mutect2, varscan2
- APOB | c.6804G>C p.Q2268H | Missense Mutation (SNP) | VAF 38/778 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV51945563; called by muse, mutect2
- APOB | c.4525C>T p.P1509S | Missense Mutation (SNP) | VAF 151/425 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV51945572; called by muse, mutect2, varscan2
- ARCN1 | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV50616425; called by muse, mutect2, varscan2
- AREG | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52645056; called by muse, varscan2
- ARHGAP30 | c.2395G>C p.D799H | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.135); catalogued as COSV63518232; called by muse, mutect2
- ARID3C | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 88/110 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV52408382; called by muse, varscan2
- ASB6 | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52965604; called by muse, mutect2, varscan2
- ASTN1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1345907735, COSV56075116; called by muse, mutect2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ATAD2 | c.2690A>G p.D897G | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV54884750; called by muse, mutect2, varscan2
- ATL2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs780577030, COSV60051443, COSV60057060; called by muse, mutect2, varscan2
- ATP2A2 | c.3118T>C p.F1040L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV57875988; called by muse, mutect2, varscan2
- ATP8B2 | c.2720A>G p.Y907C (on ENST00000672630; = p.Y874C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/514 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1209548147, COSV59247687; called by muse, mutect2, varscan2
- ATXN2L | c.965C>G p.T322S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.511); catalogued as COSV100295295, COSV57376115; called by muse, mutect2, varscan2
- B3GALNT1 | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57580897; called by muse, mutect2, varscan2
- BANP | c.722T>C p.I241T (on ENST00000286122; = p.I210T on NM_017869.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53740870; called by muse, mutect2
- BAZ2A | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV51640950; called by muse, mutect2
- BCAS3 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs751704466, COSV66769841; called by muse, mutect2, varscan2
- BCL7B | c.213T>G p.N71K | Missense Mutation (SNP) | VAF 25/538 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV56271118; called by muse, mutect2
- BCR | c.859A>G p.M287V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59934230; called by muse, mutect2, varscan2
- BEND4 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV72469291; called by muse, mutect2, varscan2
- BMPER | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs751399844, COSV51827088; called by muse, mutect2, varscan2
- BPTF | c.2879T>C p.V960A | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58843308; called by muse, mutect2, varscan2
- BRD1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs900252032, COSV53460134; called by muse, mutect2, varscan2
- BTBD6 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV59271812; called by muse, mutect2, varscan2
- C10orf71 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100110403, COSV60510613; called by muse, mutect2, varscan2
- C1S | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV100196341; called by muse, mutect2, varscan2
- C3orf20 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV53787812; called by muse, mutect2, varscan2
- C3orf56 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV67756414; called by muse, mutect2, varscan2
- C6 | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54708510; called by muse, varscan2
- C9orf24 | c.742T>C p.C248R | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV52625095; called by muse, mutect2, varscan2
- CACNA1G | c.4177A>G p.S1393G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61733774; called by muse, mutect2, varscan2
- CALCOCO2 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs759882056, COSV51953024; called by muse, mutect2, varscan2
- CAMTA2 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV61836938; called by muse, varscan2
- CAPN10 | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752039061, COSV54378439; called by muse, mutect2, varscan2
- CAPN13 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs767909947, COSV54431896; called by muse, mutect2, varscan2
- CARD14 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.874); catalogued as COSV100712558, COSV60125593; called by muse, mutect2
- CATSPERD | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58464338; called by muse, varscan2
- CATSPERD | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.184); catalogued as COSV100486897, COSV58465278; called by muse, varscan2
- CCDC74A | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs752719318, COSV54608496; called by muse, mutect2, varscan2
- CCR3 | c.293A>C p.N98T | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100656450, COSV62464992; called by muse, mutect2, varscan2
- CCT3 | c.1117A>G p.T373A | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1276110807, COSV55290567; called by muse, mutect2, varscan2
- CD163 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as COSV63134388; called by muse, mutect2, varscan2
- CD164 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs1407372999, COSV51533954; called by muse, mutect2, varscan2
- CD300A | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as COSV60409840; called by muse, mutect2, varscan2
- CD69 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV57302683, COSV57303369; called by muse, varscan2
- CDC20B | c.697T>C p.Y233H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57055281; called by muse, mutect2
- CDH17 | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV50335209; called by muse, varscan2
- CDH7 | c.506-1G>A p.X169_splice | Splice Site (SNP) | VAF 39/112 reads (35%) | catalogued as COSV59890810; called by muse, mutect2, varscan2
- CDH7 | c.2098A>C p.S700R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV59890821; called by muse, mutect2, varscan2
- CDK5 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV52524788; called by muse, mutect2, varscan2
- CELSR1 | c.3403T>C p.S1135P | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53096063; called by muse, mutect2, varscan2
- CFAP57 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV63016794; called by muse, mutect2, varscan2
- CGB2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV100031457; called by mutect2, varscan2
- CHD4 | c.2489T>C p.V830A (on ENST00000357008 / NM_001363606.2; = p.V843A on NM_001273.5) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58907495; called by muse, mutect2, varscan2
- CHRND | c.934T>C p.F312L | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV51325986; called by muse, mutect2, varscan2
- CIAO1 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55531335; called by muse, varscan2
- CLCN2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV99658191; called by muse, mutect2, varscan2
- CLCN2 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV99658193; called by muse, mutect2, varscan2
- CLN3 | c.940C>T p.R314C (on ENST00000360019 / NM_001286104.2; = p.R338C on NM_000086.2) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs776725094, COSV61107059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMPK2 | c.1154G>A p.R385K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56774611; called by muse, mutect2, varscan2
- CNGB1 | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs750191382, COSV51904428; called by muse, mutect2, varscan2
- CNPY2 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.886); catalogued as rs1233851460, COSV56264832; called by muse, mutect2, varscan2
- COL12A1 | c.3736G>A p.D1246N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV59388780; called by muse, mutect2, varscan2
- COL1A2 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs72659343, CM041284, COSV51955047; called by muse, mutect2, varscan2
- COL22A1 | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs745740457, COSV57351046; called by muse, mutect2, varscan2
- COL23A1 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66795352; called by muse, mutect2, varscan2
- COL4A3 | c.3089G>A p.G1030E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59258689; called by muse, mutect2, varscan2
- COL5A1 | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs187022757; called by muse, mutect2, varscan2
- COL5A2 | c.2257G>C p.G753R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66412639; called by muse, mutect2, varscan2
- COL6A3 | c.1415T>C p.I472T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs757316442, COSV55100806; called by muse, mutect2, varscan2
- COL7A1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs761348026, COSV60399944; called by muse, mutect2, varscan2
- COL8A1 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53737597; called by muse, mutect2, varscan2
- COPS3 | c.56-2A>G p.X19_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV52006694; called by muse, mutect2, varscan2
- CSDE1 | c.1319A>G p.N440S (on ENST00000358528 / NM_001007553.3; = p.N409S on NM_007158.6) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs149300730; called by muse, mutect2, varscan2
- CST6 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV56412486; called by muse, mutect2, varscan2
- CTIF | c.808A>G p.N270D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.395); catalogued as COSV56488780; called by muse, mutect2, varscan2
- CTNNBIP1 | c.86T>C p.M29T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV65962623; called by muse, varscan2
- CXXC5 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV56794944; called by muse, mutect2, varscan2
- CYP3A4 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs201821708, CM115451, COSV60503453; called by muse, mutect2, varscan2
- DAG1 | c.2492A>G p.Y831C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58182585; called by muse, mutect2, varscan2
- DCAF5 | c.2026A>G p.N676D | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV58461963; called by muse, mutect2, varscan2
- DDX17 | c.1745A>G p.D582G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.275); catalogued as COSV53248808, COSV53249161; called by muse, mutect2, varscan2
- DDX27 | c.1430A>G p.H477R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV65609607; called by muse, mutect2, varscan2
- DEFB115 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV68723249, COSV68723332, COSV68723346; called by muse, mutect2, varscan2
- DENND2A | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV52052816, COSV52055964; called by muse, mutect2, varscan2
- DENND2C | c.2362C>T p.Q788* (on ENST00000393274 / NM_001256404.2; = p.Q731* on NM_198459.4) | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | catalogued as COSV67923215; called by muse, mutect2, varscan2
- DISP1 | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 173/574 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV52657712, COSV52662796; called by muse, mutect2, varscan2
- DLX4 | c.586C>T p.P196S (on ENST00000240306 / NM_138281.3; = p.P124S on NM_001934.3) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs552458439, COSV99537429; called by muse, mutect2, varscan2
- DMXL2 | c.4502A>G p.Y1501C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51851964; called by muse, mutect2, varscan2
- DONSON | c.1496T>C p.V499A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV51666241; called by muse, mutect2, varscan2
- DOP1B | c.3386C>T p.S1129F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV67694890; called by muse, mutect2, varscan2
- DOT1L | c.3749A>G p.D1250G | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV67112094; called by muse, mutect2
- DSC2 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV51863741, COSV51867478; called by muse, mutect2
- DUSP21 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.91); catalogued as COSV59133829; called by muse, varscan2
- ECH1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV55489868; called by muse, mutect2, varscan2
- EFEMP1 | c.131-1G>A p.X44_splice | Splice Site (SNP) | VAF 28/71 reads (39%) | catalogued as COSV62617237; called by muse, mutect2, varscan2
- EFTUD2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs752672329, COSV68184146; called by muse, mutect2, varscan2
- EGFLAM | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.145); catalogued as COSV59311814; called by muse, mutect2, varscan2
- EGFR | c.1168C>A p.Q390K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51828861; called by muse, mutect2, varscan2
- EMCN | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV56456934; called by muse, mutect2
- EML2 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV55602357; called by muse, mutect2, varscan2
- EPC1 | c.2218A>G p.T740A | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV53928391; called by muse, varscan2
- ERCC6L | c.3637T>C p.C1213R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV57821665; called by muse, mutect2, varscan2
- ERF | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV55896934, COSV55897162; called by muse, mutect2, varscan2
- ESRRG | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63172818, COSV63183564; called by muse, mutect2, varscan2
- ESS2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52817318; called by muse, mutect2, varscan2
- ESYT1 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV57275261; called by muse, mutect2, varscan2
- EVPL | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV56914045; called by muse, mutect2, varscan2
- F11R | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1484944748, COSV57035621; called by muse, mutect2, varscan2
- FAM114A2 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs769374841; called by mutect2, varscan2
- FAM135B | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50527612, COSV50535012; called by muse, mutect2, varscan2
- FAM160B2 | c.1854A>G p.P618= | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as rs1386257807, COSV57159789; called by muse, mutect2, varscan2
- FAM47B | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV100264025; called by muse, mutect2, varscan2
- FAM91A1 | c.880T>C p.F294L | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV58238591; called by muse, mutect2, varscan2
- FAT1 | c.5756C>T p.T1919I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV101498925; called by muse, mutect2, varscan2
- FBXO46 | c.1232T>C p.L411P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58349367; called by muse, mutect2, varscan2
- FCER1A | c.229A>C p.S77R | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV63667959; called by muse, mutect2, varscan2
- FDXR | c.507+2T>C p.X169_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV53124004; called by mutect2, varscan2
- FGD4 | c.1524C>G p.D508E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.472); catalogued as COSV56787443; called by muse, mutect2, varscan2
- FGF18 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51128167; called by muse, mutect2, varscan2
- FNDC1 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs377696457; called by muse, mutect2, varscan2
- FNDC3A | c.1040T>C p.V347A (on ENST00000492622 / NM_001079673.2; = p.V291A on NM_014923.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV68134320; called by muse, mutect2, varscan2
- FOLH1 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57053660; called by muse, mutect2, varscan2
- FOXRED2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs745846804, COSV53401214; called by muse, mutect2, varscan2
- FRMD1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs776892866, COSV51960435; called by muse, mutect2, varscan2
- FRYL | c.2557A>G p.T853A | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51956040; called by muse, mutect2, varscan2
- FSCN3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56171299, COSV56171869; called by muse, mutect2, varscan2
- FUBP1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV53934064, COSV53935641; called by muse, mutect2
- FUT5 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99398504; called by mutect2, varscan2
- FZD1 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs1325637188, COSV55312622; called by muse, mutect2, varscan2
- GABRR3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760476762, COSV72084269; called by muse, mutect2
- GAS6 | c.433A>G p.K145E | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV59853936; called by muse, mutect2, varscan2
- GATA2 | c.1430C>T p.T477I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV62005856; called by muse, mutect2, varscan2
- GBX1 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52548548; called by muse, mutect2, varscan2
- GDF9 | c.1113T>G p.I371M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51526893; called by muse, mutect2, varscan2
- GFI1B | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV59746140; called by muse, mutect2
- GFPT1 | c.1385T>C p.V462A (on ENST00000357308 / NM_001244710.2; = p.V444A on NM_002056.4) | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV61949514; called by muse, mutect2, varscan2
- GGA2 | c.195G>C p.W65C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59169840; called by muse, varscan2
- GGA3 | c.692T>C p.M231T (on ENST00000537686 / NM_138619.4; = p.M198T on NM_014001.5) | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1285144136, COSV55458085; called by muse, mutect2, varscan2
- GJB4 | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1394959553, COSV58356764; called by muse, mutect2, varscan2
- GLB1L2 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60279905; called by muse, mutect2, varscan2
- GLIPR1 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs144436831; called by muse, mutect2, varscan2
- GLP1R | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64714512; called by muse, mutect2, varscan2
- GLRA2 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 132/203 reads (65%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54337416, COSV54345238; called by muse, mutect2, varscan2
- GLT8D2 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.082); catalogued as COSV62562674; called by muse, mutect2, varscan2
- GMEB2 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV56608650; called by muse, mutect2, varscan2
- GOLGA3 | c.2551A>G p.M851V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV52639037; called by muse, mutect2
- GOLGA4 | c.5433A>G p.I1811M | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV62712544; called by muse, mutect2
- GOLIM4 | c.1466A>C p.D489A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV58331141; called by muse, mutect2, varscan2
- GPR84 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs764900108, COSV57210182; called by muse, varscan2
- GPR84 | c.927T>A p.D309E | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV57210187; called by muse, varscan2
- GPRC6A | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV59954039; called by muse, mutect2, varscan2
- GPT | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52954255; called by muse, mutect2
- GRIA1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV53600207, COSV53616041; called by muse, mutect2, varscan2
- GRID2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs765119459, COSV56221182, COSV56283981; called by muse, mutect2, varscan2
- GRIK2 | c.1838G>T p.W613L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59757225; called by muse, mutect2, varscan2
- H2BC21 | c.255C>G p.N85K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV58612746; called by muse, mutect2
- HEATR3 | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | catalogued as COSV53530844; called by muse, mutect2, varscan2
- HEPACAM2 | c.1116G>A p.W372* (on ENST00000394468 / NM_001039372.4; = p.W360* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/147 reads (15%) | catalogued as COSV59062430; called by muse, mutect2, varscan2
- HEPH | c.925C>T p.H309Y (on ENST00000343002; = p.H42Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV57968986; called by muse, mutect2, varscan2
- HGS | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV61269496; called by muse, mutect2, varscan2
- HIVEP1 | c.6868C>T p.P2290S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs758035535, COSV101044641; called by muse, mutect2, varscan2
- HIVEP1 | c.6869C>T p.P2290L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs777250624, COSV65099840; called by muse, mutect2, varscan2
- HIVEP2 | c.2438C>T p.S813L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50008380; called by muse, mutect2, varscan2
- HOXA3 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV57828116; called by muse, mutect2, varscan2
- HRNR | c.2282A>C p.Q761P | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV64261038; called by muse, mutect2, varscan2
- HTATSF1 | c.823A>G p.M275V | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs775568962, COSV54480274; called by muse, mutect2, varscan2
- ICE1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV56832951; called by muse, mutect2, varscan2
- ICE1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201580742; called by muse, mutect2, varscan2
- IDNK | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99461674; called by muse, mutect2, varscan2
- IDNK | c.212+1G>A p.X71_splice | Splice Site (SNP) | VAF 33/117 reads (28%) | catalogued as COSV99461679; called by muse, mutect2, varscan2
- IFT122 | c.2483A>G p.Y828C (on ENST00000348417 / NM_052989.3; = p.Y769C on NM_018262.4) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV56206266; called by muse, mutect2, varscan2
- IFT81 | c.1112G>A p.S371N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54365159; called by muse, mutect2, varscan2
- IGHMBP2 | c.1964A>G p.N655S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753926352, COSV54824769; called by muse, mutect2, varscan2
- IL18RAP | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752348672, COSV51824160; called by muse, mutect2, varscan2
- IL18RAP | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV51826899; called by muse, mutect2, varscan2
- IL20RA | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as rs1435608517, COSV100359787; called by muse, mutect2, varscan2
- IL7R | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs770274946, COSV57411231, COSV57411318; called by muse, mutect2, varscan2
- ILF3 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1422037785, COSV51560909; called by muse, mutect2, varscan2
- INO80E | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV54231214; called by muse, mutect2, varscan2
- INPP5F | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV62822853; called by muse, mutect2
- INPP5K | c.488A>G p.H163R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV57442051; called by muse, mutect2, varscan2
- IPO7 | c.2582T>C p.I861T | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV65686308; called by muse, mutect2, varscan2
- ITGAX | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99191420; called by muse, mutect2, varscan2
- ITPRIP | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV53392702; called by muse, mutect2, varscan2
- IVNS1ABP | c.490A>T p.I164F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV62250219; called by mutect2, varscan2
- JAG2 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100077876; called by muse, mutect2
- JMJD1C | c.5713A>G p.T1905A | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV59517023; called by mutect2, varscan2
- KBTBD12 | c.925T>C p.Y309H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV59680814; called by muse, mutect2, varscan2
- KCNQ5 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV59674494; called by muse, mutect2, varscan2
- KCTD4 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61241829; called by muse, mutect2, varscan2
- KDM6B | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs751343288, COSV54677824; called by muse, mutect2, varscan2
- KHDRBS2 | c.473T>G p.F158C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55477522, COSV55490984; called by muse, mutect2, varscan2
- KIAA1109 | c.7583C>T p.S2528F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52685581; called by muse, mutect2, varscan2
- KIAA1841 | c.1172G>T p.W391L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54377397; called by muse, mutect2, varscan2
- KIF13A | c.4240G>A p.D1414N | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV52460406; called by muse, mutect2, varscan2
- KIF5A | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV99672413; called by muse, mutect2, varscan2
- KIRREL2 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs370493250, COSV52876217; called by muse, mutect2, varscan2
- KLHDC7A | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68770568, COSV68770625; called by muse, mutect2, varscan2
- KLHL3 | c.1426A>G p.M476V | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59056520; called by muse, mutect2, varscan2
- KMT2C | c.12008C>T p.P4003L | Missense Mutation (SNP) | VAF 102/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100066214; called by muse, mutect2, varscan2
- KMT2C | c.12007C>T p.P4003S | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51284172; called by muse, mutect2, varscan2
- KMT5B | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58564935; called by muse, mutect2, varscan2
- KRT2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100548277; called by muse, mutect2, varscan2
- KRT72 | c.952T>A p.Y318N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53375631; called by muse, mutect2, varscan2
- KRT79 | c.1023T>G p.Y341* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs200957413, COSV57941532, COSV57942704; called by mutect2, varscan2
- KRTAP1-5 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs766453470, COSV62624505; called by muse, mutect2, varscan2
- KRTAP26-1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62129143; called by muse, mutect2, varscan2
- KSR2 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV60388377; called by muse, mutect2, varscan2
- LCE2C | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV64228599; called by muse, varscan2
- LCP2 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50446464, COSV50459384; called by muse, mutect2, varscan2
- LENG8 | c.1876A>T p.T626S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV58729384; called by muse, mutect2, varscan2
- LHCGR | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54300874; called by muse, mutect2, varscan2
- LILRB1 | c.143G>A p.G48E (on ENST00000427581; = p.G12E on NM_006669.6) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100206870; called by muse, mutect2, varscan2
- LILRB1 | c.144G>A p.G48= (on ENST00000427581; = p.G12= on NM_006669.6) | Splice Region (SNP) | VAF 15/64 reads (23%) | catalogued as COSV61116077; called by muse, mutect2, varscan2
- LIN7A | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54025344; called by muse, mutect2, varscan2
- LIPE | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1206753877, COSV54924476; called by muse, mutect2, varscan2
- LLCFC1 | c.251A>C p.E84A (on ENST00000458732; = p.E53A on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV62336789; called by muse, mutect2
- LMBRD2 | c.1107T>A p.Y369* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV56951662; called by muse, mutect2, varscan2
- LOXL3 | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV51210826; called by muse, mutect2, varscan2
- LRIT3 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV100015818, COSV100016110; called by muse, mutect2, varscan2
- LRIT3 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100015820; called by muse, mutect2, varscan2
- LRP10 | c.1211T>C p.F404S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1017990117, COSV62078677; called by muse, mutect2
- LRP6 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 112/554 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.2); catalogued as COSV53791557; called by muse, mutect2, varscan2
- LRRC3B | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs868070081, COSV67522078; called by muse, mutect2, varscan2
- LRRFIP1 | c.1357G>C p.D453H (on ENST00000392000 / NM_001137552.2; = p.D429H on NM_004735.4) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV55254476; called by muse, mutect2, varscan2
- LY6K | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52833292; called by muse, mutect2, varscan2
- MAGEB6 | c.1048A>T p.S350C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66872717; called by muse, mutect2, varscan2
- MAMDC4 | c.2516A>G p.H839R (on ENST00000445819; = p.H760R on NM_206920.3) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.267); catalogued as rs1416811189, COSV56376830; called by muse, mutect2, varscan2
- MAP1A | c.8243G>A p.G2748E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1422554867, COSV55811284; called by muse, mutect2, varscan2
- MAP2K4 | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as COSV62259426, COSV99065842; called by muse, mutect2, varscan2
- MAP3K12 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.005); catalogued as COSV57234815; called by muse, mutect2, varscan2
- MAP3K9 | c.2564A>G p.D855G (on ENST00000554752 / NM_001284230.1; = p.D869G on NM_033141.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1433904314, COSV67122366; called by muse, mutect2
- MAPK14 | c.117-2A>G p.X39_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | catalogued as COSV57697074; called by muse, mutect2, varscan2
- MARCHF6 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 134/424 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1213351530, COSV56884733; called by muse, mutect2, varscan2
- MARK1 | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65069929; called by muse, mutect2, varscan2
- MARK3 | c.1925T>C p.V642A (on ENST00000429436 / NM_001128918.3; = p.V618A on NM_002376.6) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.168); catalogued as COSV53513997; called by mutect2, varscan2
- MARS2 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV56572040; called by muse, mutect2, varscan2
- MCOLN2 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1028552054, COSV52297955; called by muse, mutect2, varscan2
- MCPH1 | c.2443T>C p.W815R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60917540; called by muse, mutect2, varscan2
- MINDY4 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54676921; called by muse, mutect2, varscan2
- MLXIP | c.2537A>G p.E846G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV59837081, COSV59837839; called by muse, varscan2
- MTF1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV65989206, COSV65990063; called by muse, mutect2, varscan2
- MTHFD1 | c.615+2T>C p.X205_splice | Splice Site (SNP) | VAF 8/76 reads (11%) | catalogued as COSV53702503; called by muse, mutect2, varscan2
- MUC16 | c.34844G>C p.R11615T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.015); catalogued as COSV67481498; called by muse, mutect2, varscan2
- MUC16 | c.11453C>T p.P3818L | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV101198048; called by muse, mutect2, varscan2
- MXRA5 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV54244094, COSV99477026; called by muse, mutect2, varscan2
- MYO18B | c.3130C>T p.H1044Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV59139568, COSV59142914; called by muse, mutect2, varscan2
- MYO1F | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100596327; called by muse, mutect2, varscan2
- NABP2 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57192918; called by muse, mutect2, varscan2
- NCAPH | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs766296287, COSV53637690; called by muse, mutect2, varscan2
- NCLN | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1167662927, COSV55743282; called by muse, mutect2, varscan2
- NCOA5 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as COSV51646218; called by muse, mutect2, varscan2
- NDUFA9 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV56930967; called by muse, mutect2, varscan2
- NEURL4 | c.1792A>G p.T598A | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59761546; called by muse, mutect2, varscan2
- NFKBIZ | c.1435A>G p.N479D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV58201428; called by muse, mutect2, varscan2
- NIBAN2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762335780, COSV55940920; called by muse, mutect2, varscan2
- NID2 | c.3193G>A p.D1065N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV53500400; called by muse, mutect2, varscan2
- NLGN2 | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV57211344; called by muse, mutect2, varscan2
- NLRP1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52573485; called by muse, mutect2, varscan2
- NLRP5 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs780828462, COSV66763274, COSV66766342; called by muse, mutect2, varscan2
- NME9 | c.251C>T p.T84I (on ENST00000333911 / NM_001349024.2; = p.T62I on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/396 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100444537; called by muse, mutect2, varscan2
- NOBOX | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs765614989, COSV56196546; called by muse, mutect2, varscan2
- NOL7 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV50584106; called by muse, mutect2
- NOLC1 | c.840dup p.P281Tfs*5 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs759637346; called by mutect2, varscan2
- NOP56 | c.1009A>G p.R337G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61390964; called by muse, mutect2, varscan2
- NOS1 | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV57617996; called by muse, mutect2, varscan2
- NOS1 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.159); catalogued as COSV57618007; called by muse, mutect2, varscan2
- NOS3 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV52493644; called by muse, mutect2, varscan2
- NOX5 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV52993497; called by muse, mutect2, varscan2
- NPSR1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV100705955, COSV62198748; called by muse, mutect2, varscan2
- NR1H4 | c.533A>G p.N178S (on ENST00000551379 / NM_001206993.2; = p.N168S on NM_005123.4) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV51855090; called by muse, mutect2, varscan2
- NRDE2 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV62964213; called by muse, mutect2, varscan2
- NRM | c.696C>G p.H232Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV51295085, COSV51297807; called by muse, mutect2, varscan2
- NSD3 | c.4069T>C p.Y1357H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57672451; called by muse, mutect2, varscan2
- NUCKS1 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs527698728, COSV65653290; called by muse, mutect2
- NUP210 | c.4085A>G p.N1362S | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1302811838, COSV54410674; called by muse, mutect2, varscan2
- NUP210L | c.2178A>C p.L726F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55153803; called by muse, mutect2, varscan2
- NUP85 | c.1481A>G p.K494R | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV55458068; called by muse, mutect2, varscan2
- OAS3 | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57444156; called by muse, mutect2, varscan2
- OBSCN | c.16T>C p.F6L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV52806781; called by muse, mutect2, varscan2
- OPALIN | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs201145766; called by muse, mutect2, varscan2
- OR10Q1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs755585068, COSV57470089; called by muse, mutect2, varscan2
- OR10Z1 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 235/302 reads (78%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs144307016; called by muse, mutect2, varscan2
- OR2M4 | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV60709133; called by muse, mutect2
- OR4K1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs147347995, COSV53460876; called by muse, mutect2, varscan2
- OR51G1 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs1301584301, COSV58970165; called by muse, mutect2, varscan2
- OR51T1 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.883); catalogued as COSV59025535; called by muse, mutect2, varscan2
- OR52B4 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs757867926, COSV68768868; called by muse, mutect2, varscan2
- OTOGL | c.916C>T p.P306S (on ENST00000547103; = p.P297S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV72007096; called by muse, mutect2
- P4HB | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV58942442; called by muse, mutect2, varscan2
- PAK2 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV59083785; called by muse, mutect2
- PARP6 | c.1223A>G p.D408G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53004313; called by muse, mutect2, varscan2
- PCDH11Y | c.263C>T p.S88F (on ENST00000400457 / NM_032973.2; = p.S77F on NM_032971.3) | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53087313; called by muse, mutect2, varscan2
- PCDH18 | c.2530C>T p.Q844* | Nonsense Mutation (SNP) | VAF 34/141 reads (24%) | catalogued as COSV61269209; called by muse, mutect2, varscan2
- PCDHA7 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65346247; called by muse, mutect2, varscan2
- PCDHGA6 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV53999921; called by muse, mutect2, varscan2
- PCYT2 | c.760-1G>A p.X254_splice | Splice Site (SNP) | VAF 3/19 reads (16%) | catalogued as COSV58712212; called by muse, mutect2
- PDE4DIP | c.4835T>G p.F1612C | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1427360892, COSV57717328; called by muse, mutect2, varscan2
- PDE6D | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); catalogued as rs767975806, COSV55020913; called by mutect2, varscan2
- PDIA3 | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55857530; called by muse, mutect2, varscan2
- PEX14 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV63062603; called by muse, mutect2, varscan2
- PHKA2 | c.1088A>G p.K363R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV66055446; called by muse, mutect2, varscan2
- PHTF2 | c.1297C>T p.P433S (on ENST00000248550 / NM_001366089.1; = p.P395S on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV50334612; called by muse, varscan2
- PI4KA | c.5389A>G p.S1797G | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55418264; called by muse, mutect2
- PI4KA | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99744194; called by muse, mutect2, varscan2
- PIK3C2B | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV65804009; called by muse, mutect2, varscan2
- PIKFYVE | c.4088T>C p.I1363T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52246236; called by muse, mutect2, varscan2
- PIM1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV65166320; called by muse, mutect2, varscan2
- PKHD1L1 | c.9820G>A p.D3274N | Missense Mutation (SNP) | VAF 170/350 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV65749006; called by muse, mutect2, varscan2
- PKN3 | c.2333A>G p.Y778C | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV52578582; called by muse, mutect2, varscan2
- PLCH1 | c.3437G>A p.R1146Q (on ENST00000340059 / NM_001130960.2; = p.R1138Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as rs959999346, COSV58205968; called by muse, mutect2
- PLEC | c.13259T>C p.I4420T (on ENST00000322810 / NM_201380.4; = p.I4310T on NM_000445.5) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV59641995; called by muse, mutect2, varscan2
- PLEC | c.1703T>C p.V568A (on ENST00000322810 / NM_201380.4; = p.V458A on NM_000445.5) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV59671581; called by muse, mutect2, varscan2
- PLEC | c.1436T>C p.I479T (on ENST00000322810 / NM_201380.4; = p.I369T on NM_000445.5) | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV59671642; called by muse, mutect2, varscan2
- PLEKHA2 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs921838788, COSV66243246; called by muse, mutect2, varscan2
- PLPPR3 | c.526T>C p.S176P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.33); catalogued as COSV62461232; called by muse, mutect2, varscan2
- PNPLA1 | c.1226G>A p.G409E (on ENST00000394571 / NM_001374623.1; = p.G314E on NM_173676.2) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV57236611; called by muse, mutect2, varscan2
- PNPLA7 | c.3499T>C p.Y1167H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53003987; called by muse, mutect2, varscan2
- PODXL | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 251/403 reads (62%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs537767017, COSV59871970; called by muse, mutect2, varscan2
- POLK | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54037903; called by muse, mutect2, varscan2
- POLQ | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51757927; called by muse, mutect2, varscan2
- POMT2 | c.1399A>G p.I467V | Missense Mutation (SNP) | VAF 102/577 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55072670; called by muse, mutect2, varscan2
- POTEE | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs747324485, COSV58238683; called by muse, mutect2, varscan2
- PPIL1 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173515589, COSV65472932; called by muse, varscan2
- PPL | c.4798A>G p.T1600A | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs111733714, COSV52170940; called by muse, mutect2, varscan2
- PPL | c.2381A>G p.Y794C | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62049444; called by muse, mutect2, varscan2
- PPP1R10 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV64740049; called by muse, mutect2, varscan2
- PPP2R5A | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as COSV54818065; called by muse, mutect2, varscan2
- PRKDC | c.3988T>C p.Y1330H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58059551; called by muse, mutect2, varscan2
- PROX2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs1369089805, COSV71520132; called by muse, mutect2, varscan2
- PRPF8 | c.1774T>C p.Y592H | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV59266193; called by muse, mutect2, varscan2
- PRPSAP2 | c.95T>C p.M32T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV52067049; called by muse, mutect2, varscan2
- PRR14 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV54913040; called by muse, mutect2
- PRRT3 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV55978116; called by muse, mutect2, varscan2
- PRSS45P | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101373877; called by muse, mutect2, varscan2
- PTPRB | c.5581C>G p.R1861G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54248631; called by muse, mutect2, varscan2
- PTPRM | c.3662A>G p.D1221G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59873098; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV54760546; called by muse, mutect2, varscan2
- RABGAP1 | c.532T>A p.C178S | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58060740; called by muse, mutect2, varscan2
- RAC1 | c.41T>A p.V14E | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV61823732; called by muse, varscan2
- RAD51B | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as COSV66852706; called by muse, mutect2, varscan2
- RASA2 | c.542A>T p.H181L | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.288); catalogued as COSV53944053; called by muse, mutect2, varscan2
- RBM15B | c.2591A>G p.Q864R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV60045381; called by muse, mutect2, varscan2
- RBM19 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99925467; called by muse, mutect2, varscan2
- RC3H1 | c.22T>C p.W8R | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51208339; called by muse, mutect2, varscan2
- RECK | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV65035991; called by muse, mutect2
- RELN | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58994846; called by muse, mutect2, varscan2
- RETREG2 | c.1601A>G p.D534G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.051); catalogued as COSV56088466; called by muse, mutect2, varscan2
- REXO1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs777707137, COSV50085018; called by muse, mutect2, varscan2
- RGL4 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV51944876; called by muse, mutect2, varscan2
- RGPD2 | c.5203G>A p.E1735K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100552834; called by mutect2, varscan2
- RNF217 | c.1558T>A p.L520I (on ENST00000521654 / NM_001286398.2; = p.F266Y on NM_152553.5) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); catalogued as COSV51576849; called by muse, mutect2, varscan2
- RP1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV55110720; called by muse, mutect2, varscan2
- RPS6KA2 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as COSV55826338; called by muse, mutect2, varscan2
- RRAGC | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100883793; called by muse, mutect2
- RRAGC | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV65931855; called by muse, mutect2, varscan2
- RREB1 | c.2990C>T p.P997L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs370598103; called by muse, mutect2, varscan2
- RTEL1 | c.3541A>G p.I1181V | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); catalogued as rs376148207; called by muse, mutect2, varscan2
- RTN3 | c.1703A>G p.Q568R (on ENST00000377819 / NM_001265589.2; = p.Q549R on NM_201428.3) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58030755; called by muse, mutect2, varscan2
- SACM1L | c.1240-1G>A p.X414_splice | Splice Site (SNP) | VAF 44/165 reads (27%) | catalogued as COSV66614502; called by muse, varscan2
- SAE1 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54297543; called by muse, mutect2, varscan2
- SALL4 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV53854751; called by muse, mutect2, varscan2
- SBK1 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs768691439, COSV59398323; called by muse, mutect2, varscan2
- SCAMP2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99173917; called by muse, mutect2, varscan2
- SCARF1 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV53960557; called by muse, mutect2, varscan2
- SCN11A | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56572746; called by muse, mutect2, varscan2
- SCN11A | c.1788G>A p.M596I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV100180894; called by muse, mutect2, varscan2
- SCN4A | c.3704T>G p.L1235R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71128074; called by muse, mutect2, varscan2
- SCN4A | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.199); catalogued as rs1197093499, COSV71128075; called by muse, mutect2, varscan2
- SCN5A | c.5139G>A p.W1713* (on ENST00000333535 / NM_198056.3; = p.W1712* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as COSV61134679; called by muse, mutect2, varscan2
- SCN5A | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV61134705; called by muse, varscan2
- SCN7A | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV69273585; called by muse, varscan2
- SCRIB | c.3811C>G p.L1271V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100253903, COSV57591105; called by muse, mutect2
- SCRIB | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57591118; called by muse, mutect2
- SEC23B | c.1544T>C p.I515T | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs1334546233, COSV52722058; called by muse, mutect2, varscan2
- SEC24C | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV59543904; called by muse, mutect2, varscan2
- SEMA3A | c.2086A>G p.T696A | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54881805; called by muse, mutect2, varscan2
- SEPTIN4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV57898063; called by muse, mutect2, varscan2
- SERPINF1 | c.644-1G>A p.X215_splice | Splice Site (SNP) | VAF 33/90 reads (37%) | catalogued as COSV54616918; called by muse, mutect2, varscan2
- SETX | c.6467G>C p.S2156T | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56390716; called by muse, mutect2, varscan2
- SFXN4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV53720197; called by muse, mutect2, varscan2
- SGCG | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs867039495, COSV54555841; called by muse, mutect2, varscan2
- SGIP1 | c.2465G>A p.G822E | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs866082520, COSV52775348; called by muse, mutect2, varscan2
- SHC3 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65439874; called by muse, mutect2, varscan2
- SIAE | c.961G>T p.V321F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461562446, COSV99703741; called by muse, mutect2, varscan2
- SLC29A1 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57579707; called by muse, mutect2
- SLC29A3 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs773495153, COSV64384606; called by muse, mutect2, varscan2
- SLC2A1 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV65288000; called by muse, mutect2, varscan2
- SLC5A1 | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56687864; called by muse, varscan2
- SLC5A12 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV101237714, COSV68450447; called by muse, mutect2, varscan2
- SLC5A3 | c.2087T>A p.V696E | Missense Mutation (SNP) | VAF 70/562 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV62972133; called by muse, mutect2, varscan2
- SLCO1A2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV56601703; called by muse, mutect2, varscan2
- SLCO3A1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.726); catalogued as COSV59240135; called by muse, mutect2, varscan2
- SLFN12 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.943); catalogued as COSV59227046; called by muse, mutect2, varscan2
- SLU7 | c.1709G>C p.R570T | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV51789306; called by muse, mutect2
- SMARCD3 | c.1061A>G p.K354R (on ENST00000262188 / NM_001003801.2; = p.K341R on NM_003078.4) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.248); catalogued as COSV50396561; called by muse, mutect2, varscan2
- SMC4 | c.2309A>G p.E770G | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as COSV61006842; called by muse, mutect2, varscan2
- SNRNP200 | c.5206T>C p.F1736L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60492854; called by muse, mutect2, varscan2
- SNW1 | c.740T>G p.I247S | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV55055717; called by muse, mutect2, varscan2
- SNX17 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV52009361, COSV52010313; called by muse, mutect2, varscan2
- SPAG5 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58803366; called by muse, mutect2, varscan2
- SPATA16 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV63531733; called by muse, mutect2, varscan2
- SPECC1 | c.202T>A p.S68T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV54963071; called by muse, varscan2
- SPEN | c.6787A>T p.M2263L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated, low confidence (0.67); PolyPhen possibly damaging (0.448); catalogued as COSV65365584; called by muse, mutect2, varscan2
- SPRY3 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100249134; called by muse, mutect2, varscan2
- SRCAP | c.2669T>C p.V890A | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52677936; called by muse, mutect2, varscan2
- SRP54 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV53740928; called by muse, mutect2, varscan2
- STK11 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV58826655; called by muse, mutect2, varscan2
- STK4 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65671445; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100562161, COSV59135095; called by muse, mutect2, varscan2
- SUMO2 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV58813897; called by muse, mutect2, varscan2
- SYK | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65327383; called by muse, mutect2, varscan2
- SYNE1 | c.20819C>T p.S6940F (on ENST00000367255 / NM_182961.4; = p.S6869F on NM_033071.3) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs1171279885, COSV54969803; called by muse, mutect2, varscan2
- SYNE3 | c.2195A>G p.E732G | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV62081300; called by muse, mutect2, varscan2
- SYNM | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV60367106; called by muse, mutect2, varscan2
- SYPL2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 153/305 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs754225841, COSV63995202; called by muse, mutect2, varscan2
- TAF2 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1474957667, COSV65419802; called by muse, mutect2
- TAF6L | c.1847A>G p.Y616C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV99584902; called by muse, mutect2, varscan2
- TASOR2 | c.3323G>A p.R1108K | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1274707535, COSV60168771; called by muse, mutect2, varscan2
- TCF15 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs529618347, COSV55721182; called by muse, mutect2
- TCF25 | c.2023T>G p.W675G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1347106912, COSV54531285; called by muse, mutect2, varscan2
- TCF4 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.039); catalogued as COSV61902653; called by muse, mutect2, varscan2
- TEPSIN | c.1510T>C p.S504P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs1200171648, COSV56144061; called by muse, mutect2, varscan2
- TERT | c.2758G>A p.V920I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV57230281; called by muse, mutect2, varscan2
- TESPA1 | c.839G>A p.R280K (on ENST00000316577 / NM_001098815.3; = p.R142K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.915); catalogued as COSV57260332; called by muse, mutect2, varscan2
- TET2 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54397706, COSV54408194, COSV54425004; called by muse, mutect2, varscan2
- TGM1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs536915231, COSV52864554; called by muse, mutect2, varscan2
- TIMM44 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs766220039, COSV54493587; called by muse, mutect2, varscan2
- TLE1 | c.242T>A p.I81N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64686511; called by muse, varscan2
- TLR9 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.346); catalogued as COSV59727204; called by mutect2, varscan2
- TM9SF2 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV64507211; called by muse, mutect2, varscan2
- TM9SF4 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV54109873; called by muse, mutect2, varscan2
- TMEM251 | c.386T>C p.V129A (on ENST00000415050 / NM_001098621.4; = p.V97A on NM_015676.3) | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.699); catalogued as COSV52093118; called by muse, mutect2, varscan2
- TMX3 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs998201023, COSV55186800; called by muse, mutect2, varscan2
- TNFRSF10A | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as rs1021603055, COSV55326583; called by muse, mutect2, varscan2
- TNXB | c.4322G>A p.R1441K (on ENST00000647633; = p.R1194K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/305 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.198); catalogued as COSV64485043; called by muse, mutect2, varscan2
- TOP2B | c.2921T>A p.L974* (on ENST00000264331 / NM_001330700.2; = p.L969* on NM_001068.3) | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV51975314; called by muse, mutect2, varscan2
- TRH | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1410447242, COSV57015475; called by muse, varscan2
- TRH | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as rs1350242063, COSV57015480; called by muse, varscan2
- TRHDE | c.2120G>C p.R707P | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.459); catalogued as COSV53857265; called by muse, mutect2, varscan2
- TRIO | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV60090330; called by muse, mutect2, varscan2
- TRPC6 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.89); catalogued as COSV60258707; called by muse, mutect2, varscan2
- TRRAP | c.3731A>G p.D1244G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1554412905, COSV62850956; called by muse, mutect2, varscan2
- TSEN54 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51382275; called by muse, mutect2
- TSN | c.283T>G p.L95V | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.209); catalogued as COSV67605733; called by muse, mutect2, varscan2
- TSPAN1 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs749059460, COSV64340523; called by muse, mutect2, varscan2
- TTN | c.31717G>A p.E10573K (on ENST00000591111; = p.E9646K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | PolyPhen benign (0.001); catalogued as COSV60231522; called by muse, mutect2, varscan2
- TTN | c.29144G>A p.G9715D (on ENST00000591111; = p.G8788D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/144 reads (26%) | PolyPhen benign (0.025); catalogued as COSV100593146; called by muse, mutect2, varscan2
- TTN | c.29143G>A p.G9715S (on ENST00000591111; = p.G8788S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/143 reads (26%) | PolyPhen benign (0.031); catalogued as COSV100593149; called by muse, mutect2, varscan2
- TTN | c.14785G>C p.A4929P (on ENST00000591111; = p.A4002P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/119 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV60231533; called by muse, mutect2, varscan2
- TUBAL3 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as COSV66814575; called by muse, mutect2, varscan2
- TWNK | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52970637; called by muse, mutect2, varscan2
- UBAP2 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.428); catalogued as COSV62548170; called by muse, mutect2, varscan2
- UBR2 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65769776; called by muse, mutect2
- UCMA | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV66321887; called by muse, mutect2, varscan2
- UGT1A5 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as rs748267657, COSV59394778; called by muse, mutect2, varscan2
- UHRF1BP1L | c.701T>C p.L234S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217447644, COSV54440727; called by muse, mutect2
- ULBP1 | c.610A>T p.M204L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV57664750; called by muse, mutect2, varscan2
- UNC13B | c.4502A>G p.N1501S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as rs960263285, COSV61469997; called by muse, mutect2, varscan2
- UNKL | c.2144C>T p.P715L (on ENST00000389221 / NM_001372107.1; = p.P665L on NM_001193388.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs747707221, COSV99201394; called by muse, varscan2
- UNKL | c.2143C>T p.P715S (on ENST00000389221 / NM_001372107.1; = p.P665S on NM_001193388.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.096); catalogued as COSV99201395; called by muse, mutect2, varscan2
- UQCRC1 | c.130T>C p.F44L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1175424221, COSV52552646; called by muse, mutect2, varscan2
- USH2A | c.13400C>T p.P4467L | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56408907, COSV56431815; called by muse, mutect2, varscan2
- USH2A | c.9944A>T p.Y3315F | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV56360938, COSV56408918; called by muse, mutect2, varscan2
- USP19 | c.1808A>C p.D603A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60047531; called by muse, mutect2, varscan2
- USP20 | c.1451A>G p.D484G | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV59616973; called by muse, mutect2, varscan2
- USP6NL | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs774742937, COSV53214014; called by muse, mutect2, varscan2
- VIL1 | c.2029A>G p.T677A | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV50292909; called by muse, mutect2, varscan2
- VIT | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.138); catalogued as rs148935502; called by muse, mutect2, varscan2
- VNN2 | c.1190A>G p.E397G | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV58473619; called by muse, mutect2
- VPS13B | c.5146A>G p.T1716A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV62151893; called by muse, mutect2
- VPS39 | c.344A>G p.K115R (on ENST00000348544 / NM_001301138.2; = p.K104R on NM_015289.5) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.503); catalogued as COSV58791920; called by muse, mutect2, varscan2
- WDR83 | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV52952825; called by muse, mutect2, varscan2
- WNT7A | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV53201109; called by muse, mutect2, varscan2
- WNT9B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as COSV51519491; called by muse, mutect2, varscan2
- XRCC1 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV53451574; called by muse, mutect2, varscan2
- YWHAQ | c.650T>G p.I217S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53004200; called by muse, mutect2, varscan2
- ZC3H14 | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51772011; called by muse, mutect2, varscan2
- ZDBF2 | c.1898G>A p.G633E | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65628592; called by muse, mutect2, varscan2
- ZDHHC9 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV64097147; called by muse, mutect2, varscan2
- ZFAND2A | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.088); catalogued as COSV100335812; called by muse, mutect2, varscan2
- ZFC3H1 | c.2149A>G p.S717G | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV66434732; called by muse, mutect2, varscan2
- ZFYVE19 | c.1346A>G p.H449R (on ENST00000355341 / NM_001077268.2; = p.H439R on NM_032850.5) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762632180, COSV54541620; called by muse, mutect2, varscan2
- ZFYVE26 | c.6134C>A p.A2045D | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV61331742; called by muse, mutect2, varscan2
- ZNF132 | c.1973T>C p.I658T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs763424946, COSV54235738; called by muse, mutect2, varscan2
- ZNF334 | c.1312T>C p.C438R | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61619617; called by muse, mutect2, varscan2
- ZNF34 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV58640741; called by muse, mutect2, varscan2
- ZNF451 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV62596939, COSV62599047; called by muse, mutect2, varscan2
- ZNF484 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60259031; called by muse, mutect2, varscan2
- ZNF652 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62948212; called by muse, mutect2, varscan2
- ZNF669 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs763192149, COSV58537666; called by muse, mutect2, varscan2
- ZNF683 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV62874163; called by muse, mutect2, varscan2
- ZNF746 | c.1679A>G p.H560R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61408424; called by muse, mutect2
- ZNF831 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs754503516, COSV64043362; called by muse, mutect2, varscan2
- ZSCAN18 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as rs1476960471, COSV99559056; called by muse, mutect2, varscan2
- CGB3 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by mutect2, varscan2
- PTPN20 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIOX1 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- ABCC12 | c.1746G>A p.Q582= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs971086196, COSV60916612; called by muse, mutect2, varscan2
- ABI3BP | c.3141T>C p.G1047= | Silent (SNP) | VAF 36/189 reads (19%) | catalogued as COSV52545503; called by muse, mutect2, varscan2
- ADAD1 | c.603G>A p.G201= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs181655842, COSV99635043; called by muse, mutect2, varscan2
- ADGRF5 | c.2142G>A p.E714= | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as COSV51937895; called by muse, mutect2, varscan2
- AHNAK | c.7293A>G p.G2431= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV57223900; called by muse, mutect2, varscan2
- ALG3 | c.747C>T p.F249= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV56613286; called by muse, mutect2, varscan2
- ANLN | c.1140T>C p.R380= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV56078275; called by muse, mutect2, varscan2
- ANO3 | c.1926C>T p.F642= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56791793; called by muse, mutect2, varscan2
- AOX1 | c.409C>T p.L137= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV65983092; called by muse, mutect2, varscan2
- ARID2 | c.4509T>G p.V1503= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as COSV57606835, COSV57610899; called by muse, mutect2, varscan2
- ATG2A | c.3078A>G p.E1026= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1446412180, COSV65967975; called by muse, mutect2, varscan2
- ATG2A | c.102C>T p.S34= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV65967980; called by muse, mutect2, varscan2
- ATP4A | c.609G>A p.E203= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV52870396; called by muse, mutect2, varscan2
- ATP5F1C | c.276C>T p.L92= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as COSV59622502; called by muse, mutect2, varscan2
- B4GALNT2 | c.1642C>A p.R548= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs558063592, COSV55927569; called by muse, mutect2, varscan2
- BACE1 | c.717T>C p.G239= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV57285784; called by muse, mutect2, varscan2
- BNIP1 | c.333A>G p.K111= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV51571546; called by muse, mutect2, varscan2
- BRCA2 | c.6537T>G p.V2179= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV66459107; called by muse, mutect2, varscan2
- C1S | c.477C>T p.P159= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV100196343; called by muse, mutect2, varscan2
- C1orf112 | c.927A>G p.T309= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV53681339; called by muse, mutect2
- CADPS | c.2040C>T p.S680= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV51894058; called by muse, mutect2, varscan2
- CAMTA2 | c.1779G>A p.G593= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100772327; called by muse, mutect2, varscan2
- CBLN4 | c.309T>C p.G103= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV50353801; called by muse, mutect2, varscan2
- CCDC174 | c.126A>G p.G42= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV57981754; called by muse, mutect2
- CDC27 | c.726T>A p.P242= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV50631742; called by muse, mutect2, varscan2
- CDC5L | c.828A>G p.P276= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs1202426118, COSV65176809; called by muse, mutect2, varscan2
- CDK20 | c.681C>T p.V227= (on ENST00000325303 / NM_001039803.3; = p.V206= on NM_012119.4) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs376165656, COSV57483710; called by muse, mutect2, varscan2
- CDKAL1 | c.987A>G p.V329= | Silent (SNP) | VAF 83/529 reads (16%) | catalogued as COSV51187572; called by muse, mutect2, varscan2
- CEACAM5 | c.1548G>A p.K516= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs201069007, COSV55750652; called by muse, mutect2, varscan2
- CELF4 | c.1011G>A p.G337= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs753154580, COSV58461351; called by muse, mutect2
- CELSR3 | c.9519C>T p.P3173= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV50971295; called by muse, mutect2, varscan2
- CEMIP2 | c.3510A>G p.A1170= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV65488615; called by muse, mutect2, varscan2
- CENPF | c.8289T>C p.T2763= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as COSV65277415; called by muse, mutect2, varscan2
- CENPF | c.8742T>C p.P2914= | Silent (SNP) | VAF 26/243 reads (11%) | catalogued as COSV65277421; called by muse, mutect2, varscan2
- CGNL1 | c.3624G>A p.L1208= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV55572484; called by muse, mutect2, varscan2
- CHPF2 | c.366T>C p.R122= | Silent (SNP) | VAF 22/219 reads (10%) | catalogued as COSV50396560; called by muse, mutect2
- COL5A1 | c.2982C>T p.G994= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs377265020; called by muse, mutect2, varscan2
- COL7A1 | c.3939C>T p.A1313= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs141825319; called by muse, mutect2, varscan2
- COL7A1 | c.660T>C p.G220= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV60399957; called by muse, mutect2, varscan2
- CPA5 | c.708C>T p.L236= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs374574488, COSV100812492; called by muse, mutect2
- CSE1L | c.1464T>C p.I488= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV53703897; called by muse, mutect2, varscan2
- CSH2 | c.492C>T p.I164= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as COSV61080442, COSV61080830; called by muse, mutect2, varscan2
- CUL9 | c.4107G>A p.K1369= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV52732257; called by muse, mutect2, varscan2
- CYP1A1 | c.435C>T p.F145= | Silent (SNP) | VAF 64/175 reads (37%) | catalogued as COSV65697871; called by muse, mutect2, varscan2
- DAPK1 | c.4098C>T p.T1366= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs774013763, COSV63790062; called by muse, mutect2, varscan2
- DBX1 | c.645G>A p.A215= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV57054823; called by muse, mutect2, varscan2
- DCC | c.147C>T p.A49= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs777555256, COSV59122660; called by muse, mutect2, varscan2
- DDX21 | c.465T>C p.P155= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV62556286; called by muse, mutect2, varscan2
- DDX24 | c.1803A>G p.K601= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV58213355; called by muse, mutect2, varscan2
- DEFB127 | c.60A>G p.Q20= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV66688923; called by muse, mutect2
- DHX40 | c.168G>A p.Q56= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV52069218; called by muse, mutect2, varscan2
- DIPK1C | c.990T>C p.C330= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100679739; called by muse, mutect2, varscan2
- DNAJB6 | c.216A>G p.G72= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as COSV51098187; called by muse, mutect2
- DPPA5 | c.204C>T p.V68= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV64875862; called by muse, mutect2, varscan2
- EHBP1L1 | c.2535G>A p.E845= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1311127829, COSV58574337; called by muse, mutect2, varscan2
- ENTR1 | c.729T>C p.S243= (on ENST00000357365 / NM_001039707.2; = p.S220= on NM_006643.4) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV53742644; called by muse, mutect2, varscan2
- EPHA8 | c.2496G>A p.L832= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV51282057; called by muse, mutect2, varscan2
- EPHB6 | c.618C>G p.T206= | Silent (SNP) | VAF 42/526 reads (8%) | catalogued as rs1377812887, COSV67420123; called by muse, mutect2
- EPPK1 | c.261C>T p.L87= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs556305553, COSV73262097; called by muse, mutect2, varscan2
- ESS2 | c.864C>T p.I288= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99350588; called by muse, mutect2, varscan2
- ESYT2 | c.2640C>T p.F880= (on ENST00000613624; = p.F804= on NM_020728.3) | Silent (SNP) | VAF 262/456 reads (57%) | catalogued as rs746234331, COSV51754593; called by muse, mutect2
- FAM47B | c.1101G>A p.Q367= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV100264022; called by muse, mutect2, varscan2
- FAM83H | c.1446T>C p.G482= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1554623066, COSV66354344; called by muse, mutect2
- FANCB | c.1302T>C p.D434= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV60761152; called by muse, mutect2
- FAT1 | c.5757C>T p.T1919= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs779716177, COSV71671709; called by muse, mutect2, varscan2
- FAT4 | c.1962C>T p.F654= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs879016380, COSV101272531, COSV67895071; called by muse, mutect2, varscan2
- FBN3 | c.2637C>T p.V879= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs866508921, COSV54453174, COSV54467964; called by muse, mutect2, varscan2
- FBXW11 | c.429T>C p.S143= | Silent (SNP) | VAF 65/186 reads (35%) | catalogued as COSV51612253; called by muse, mutect2, varscan2
- FCGBP | c.2634G>A p.R878= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- FEM1B | c.1527T>C p.F509= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as rs1434823209, COSV60989205; called by muse, mutect2, varscan2
- FER1L6 | c.5181C>T p.A1727= | Silent (SNP) | VAF 80/322 reads (25%) | catalogued as COSV67551858; called by muse, mutect2, varscan2
- FLNC | c.6639C>T p.V2213= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs747628268, COSV57961194; ClinVar: likely benign; called by muse, varscan2
- FMR1 | c.1197A>G p.V399= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV54426199; called by muse, mutect2, varscan2
- FNDC1 | c.1299C>T p.F433= | Silent (SNP) | VAF 99/179 reads (55%) | catalogued as COSV51930815; called by muse, mutect2, varscan2
- FNDC3B | c.2913T>C p.P971= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV61046941; called by muse, mutect2, varscan2
- FOXM1 | c.933C>T p.H311= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV61206997; called by muse, mutect2, varscan2
- FRY | c.1971T>C p.D657= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as COSV66575633; called by muse, mutect2, varscan2
- GBA2 | c.1803A>G p.E601= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV62306520; called by muse, mutect2, varscan2
- GNB1L | c.402G>A p.G134= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV61549265; called by muse, mutect2, varscan2
- GOLGA5 | c.1074T>C p.D358= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV50834407; called by muse, mutect2, varscan2
- HBB | c.183G>A p.V61= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs1315584635, COSV58942883; called by muse, mutect2, varscan2
- HDLBP | c.549A>G p.K183= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs1223022371, COSV60498904, COSV60499278; called by muse, mutect2, varscan2
- HHIPL2 | c.1614G>A p.K538= | Silent (SNP) | VAF 185/1039 reads (18%) | catalogued as COSV58566647; called by muse, mutect2, varscan2
- HLTF | c.2652C>T p.S884= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV59502538; called by muse, mutect2, varscan2
- IDH3G | c.282T>C p.N94= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54209221; called by muse, mutect2
- IFT172 | c.1275T>C p.N425= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV53137021; called by muse, mutect2, varscan2
- IL22RA1 | c.543G>A p.G181= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV54629689; called by muse, mutect2, varscan2
- IL25 | c.411G>A p.Q137= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV59307223; called by muse, mutect2, varscan2
- KIAA0513 | c.337T>C p.L113= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV50742862; called by muse, mutect2, varscan2
- KIF2C | c.2151A>G p.Q717= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV64763954, COSV64765290; called by muse, mutect2, varscan2
- KRT2 | c.807G>A p.E269= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs542809502, COSV100548279; called by muse, mutect2, varscan2
- KRT4 | c.1014G>A p.Q338= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV53408893; called by muse, mutect2, varscan2
- KRT71 | c.1146G>T p.R382= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57288982, COSV57292210; called by muse, varscan2
- KRT85 | c.942C>T p.Y314= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs780063613, COSV57737741; called by muse, mutect2, varscan2
- LETM1 | c.1857C>T p.I619= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs763264804, COSV57099977; called by muse, mutect2, varscan2
- LGALS3BP | c.1563A>G p.K521= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV53165635; called by muse, mutect2, varscan2
- LIMCH1 | c.519T>C p.S173= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV58291384; called by muse, mutect2
- LIPI | c.471G>A p.L157= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV60714569; called by muse, mutect2, varscan2
- LMAN1L | c.168T>C p.H56= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1453990636, COSV59002935; called by muse, mutect2, varscan2
- LPGAT1 | c.492G>A p.K164= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV65352170; called by muse, mutect2, varscan2
- LRFN3 | c.141G>A p.G47= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV55818603; called by muse, mutect2
- LRIT3 | c.1230C>T p.F410= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV59986691; called by muse, mutect2, varscan2
- LTB4R | c.324C>T p.I108= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV51867143; called by muse, mutect2, varscan2
- LYVE1 | c.909C>T p.N303= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as rs895343667, COSV56283263; called by muse, mutect2, varscan2
- MAP3K9 | c.2604G>A p.E868= (on ENST00000554752 / NM_001284230.1; = p.E882= on NM_033141.4) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV67122362; called by muse, mutect2
- MAPT | c.2232G>A p.S744= (on ENST00000262410 / NM_001377265.1; = p.S352= on NM_005910.5) | Silent (SNP) | VAF 57/172 reads (33%) | catalogued as rs754743520, COSV52244981; called by muse, varscan2
- MDN1 | c.8277C>T p.I2759= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV65519209; called by muse, mutect2, varscan2
- MED7 | c.183T>C p.S61= | Silent (SNP) | VAF 102/474 reads (22%) | catalogued as COSV53850490; called by muse, mutect2, varscan2
- MINK1 | c.768G>A p.K256= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV61791877; called by muse, mutect2, varscan2
- MUC16 | c.4932C>T p.T1644= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV67481500; called by muse, mutect2, varscan2
- MYF6 | c.150G>A p.P50= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs556819653, COSV57350812; called by muse, mutect2, varscan2
- MYH13 | c.5331G>A p.Q1777= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV52837056; called by muse, varscan2
- MYO1F | c.2055G>A p.L685= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV100596328; called by mutect2, varscan2
- NARS1 | c.1026T>C p.C342= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV56877333; called by muse, mutect2, varscan2
- NAV1 | c.1590G>A p.K530= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV55222727; called by muse, mutect2, varscan2
- NCKIPSD | c.330A>C p.S110= | Silent (SNP) | VAF 29/212 reads (14%) | catalogued as COSV53662650; called by muse, mutect2, varscan2
- NCOR2 | c.6654T>C p.G2218= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV62301598; called by muse, mutect2, varscan2
- NCOR2 | c.1206T>C p.A402= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV62301606; called by muse, mutect2, varscan2
- NDST4 | c.285C>T p.I95= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV52120650, COSV52130325; called by muse, mutect2, varscan2
- NLRC3 | c.2412G>A p.V804= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57093915; called by muse, mutect2, varscan2
- NME9 | c.252C>T p.T84= (on ENST00000333911 / NM_001349024.2; = p.T62= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/393 reads (26%) | catalogued as COSV100444535; called by muse, mutect2, varscan2
- NOBOX | c.789G>T p.G263= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV56196536; called by muse, mutect2, varscan2
- NPHS1 | c.2937C>T p.A979= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV62289235; called by muse, mutect2, varscan2
- NR2F1 | c.1092C>T p.P364= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs371426115; called by muse, mutect2, varscan2
- NSMAF | c.1551A>G p.K517= | Silent (SNP) | VAF 28/262 reads (11%) | catalogued as COSV50695264; called by muse, mutect2, varscan2
- NT5C1B | c.84G>A p.K28= | Silent (SNP) | VAF 52/155 reads (34%) | catalogued as COSV58397883; called by muse, mutect2, varscan2
- OAS3 | c.2979G>A p.E993= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99966005; called by muse, mutect2, varscan2
- OASL | c.594C>T p.F198= | Silent (SNP) | VAF 131/375 reads (35%) | catalogued as rs759301773, COSV57477529; called by muse, mutect2, varscan2
- OLFM3 | c.1245G>A p.K415= (on ENST00000338858 / NM_001288821.1; = p.K395= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/127 reads (62%) | catalogued as COSV58801765; called by muse, mutect2, varscan2
- OR13C3 | c.492C>T p.I164= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV66166094; called by muse, mutect2, varscan2
- OR1J4 | c.879G>A p.R293= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV61589852; called by muse, mutect2, varscan2
- OR4N5 | c.633C>T p.F211= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV61321028; called by muse, mutect2, varscan2
- OR8S1 | c.36C>T p.F12= | Silent (SNP) | VAF 46/164 reads (28%) | catalogued as COSV59600413; called by muse, mutect2, varscan2
- OSBPL1A | c.1356T>G p.T452= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV60201358; called by muse, mutect2, varscan2
- PAPPA | c.3720G>A p.V1240= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV60288971; called by muse, mutect2, varscan2
- PCARE | c.2118C>T p.I706= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV59056614; called by muse, mutect2, varscan2
- PCDH15 | c.5007C>T p.F1669= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as COSV57362879; called by muse, mutect2, varscan2
- PCDHGC5 | c.1890A>G p.T630= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV52761617; called by muse, mutect2, varscan2
- PDE8A | c.1239A>G p.E413= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV59639334; called by muse, mutect2, varscan2
- PELI2 | c.658T>C p.L220= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV50713938; called by muse, mutect2, varscan2
- PGM3 | c.1071C>T p.H357= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV52285309; called by muse, mutect2, varscan2
- PHF12 | c.1338T>C p.H446= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV52021020; called by muse, mutect2, varscan2
- PHF21A | c.1491T>C p.S497= (on ENST00000418153 / NM_001101802.3; = p.S451= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1265702111, COSV99138035; called by muse, mutect2, varscan2
- PHLDB1 | c.2199T>C p.R733= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs782737862, COSV61880892; called by muse, mutect2, varscan2
- PIKFYVE | c.786T>C p.R262= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV52246225; called by muse, mutect2, varscan2
- PLCD3 | c.1365G>A p.V455= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV59562020; called by muse, mutect2, varscan2
- PLCE1 | c.909C>T p.F303= | Silent (SNP) | VAF 63/115 reads (55%) | catalogued as rs761158188, COSV53363624; called by muse, mutect2, varscan2
- PLCG2 | c.2922C>T p.L974= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV63873454; called by muse, mutect2, varscan2
- PLCL2 | c.1941C>T p.S647= (on ENST00000615277 / NM_001144382.2; = p.S521= on NM_015184.5) | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV67624021; called by muse, mutect2, varscan2
- PLXNA2 | c.3675G>A p.S1225= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1001574868, COSV65441636; called by muse, mutect2, varscan2
- PLXNA4 | c.543C>T p.D181= | Silent (SNP) | VAF 29/212 reads (14%) | catalogued as COSV58148527; called by muse, varscan2
- PODXL2 | c.1002C>T p.S334= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV61066129; called by muse, mutect2, varscan2
- PRAMEF17 | c.597G>A p.L199= | Silent (SNP) | VAF 242/370 reads (65%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.1425G>A p.R475= | Silent (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- PRDM14 | c.1290G>A p.R430= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV52574174; called by muse, mutect2, varscan2
- PRELP | c.186C>T p.L62= | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as rs991095688, COSV58116981; called by muse, mutect2, varscan2
- PREX2 | c.3711G>A p.R1237= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV55748771; called by muse, mutect2, varscan2
- PRRC2A | c.5685A>G p.L1895= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV52993549; called by muse, mutect2, varscan2
- PRSS45P | c.474C>T p.S158= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV70577654; called by muse, mutect2, varscan2
- PSG8 | c.9C>T p.L3= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs753133021, COSV60613970; called by muse, mutect2, varscan2
- PTCHD3 | c.624C>T p.F208= | Silent (SNP) | VAF 47/81 reads (58%) | catalogued as rs1279965869, COSV71256250; called by muse, mutect2, varscan2
- PTPN12 | c.2016T>C p.D672= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as COSV50367329; called by muse, mutect2
- PTPRT | c.654G>A p.K218= | Silent (SNP) | VAF 66/208 reads (32%) | catalogued as COSV62004450; called by muse, mutect2, varscan2
- RAMP3 | c.384T>C p.V128= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as COSV54246452; called by muse, mutect2, varscan2
- RAP1GDS1 | c.651A>G p.E217= (on ENST00000408927 / NM_001100427.2; = p.E218= on NM_021159.5) | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs764619055, COSV52790092; called by muse, mutect2, varscan2
- RB1 | c.615A>G p.V205= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV57318783; called by muse, mutect2, varscan2
- RBM19 | c.1728C>T p.S576= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs773546444, COSV99925466; called by muse, mutect2, varscan2
- RBM23 | c.780T>C p.G260= (on ENST00000359890 / NM_001077351.2; = p.G244= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as COSV57128510; called by muse, mutect2, varscan2
- RHO | c.21T>C p.P7= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV56214256; called by muse, mutect2, varscan2
- RPS6KA2 | c.267C>T p.A89= | Silent (SNP) | VAF 59/104 reads (57%) | catalogued as COSV55826365, COSV99691104; called by muse, mutect2, varscan2
- RPTN | c.63G>A p.G21= | Silent (SNP) | VAF 51/75 reads (68%) | catalogued as COSV60168383; called by muse, mutect2, varscan2
- RYR2 | c.819C>T p.S273= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs746461178, COSV100772837, COSV63693234; ClinVar: likely benign; called by muse, mutect2, varscan2
- S1PR3 | c.789C>T p.F263= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV63981047; called by muse, mutect2, varscan2
- SAMD9 | c.1566G>A p.R522= | Silent (SNP) | VAF 147/225 reads (65%) | catalogued as COSV66076890; called by muse, mutect2, varscan2
- SCAMP2 | c.561C>T p.S187= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99173916; called by muse, mutect2, varscan2
- SEC62 | c.291A>G p.V97= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV61261854; called by muse, mutect2, varscan2
- SF3B3 | c.2232T>C p.G744= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV56789849; called by muse, mutect2, varscan2
- SFMBT1 | c.1308T>C p.D436= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV56256117; called by muse, mutect2, varscan2
- SH2D7 | c.1158G>A p.R386= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV51949483; called by muse, mutect2, varscan2
- SIAE | c.960T>C p.L320= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99703743; called by muse, mutect2, varscan2
- SIGLEC12 | c.1188C>T p.S396= (on ENST00000291707 / NM_053003.4; = p.S278= on NM_033329.2) | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV52459789, COSV52463601; called by muse, mutect2, varscan2
- SIRT2 | c.234A>G p.R78= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV50876114; called by muse, mutect2
- SKAP1 | c.195G>A p.Q65= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV61149968; called by muse, mutect2, varscan2
- SLC46A2 | c.681A>G p.L227= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV65290277; called by muse, mutect2, varscan2
- SLC4A7 | c.189A>G p.G63= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs1175472250, COSV55400789; called by muse, mutect2, varscan2
- SLC6A2 | c.1168C>T p.L390= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs527764485, COSV54920786, COSV54923829; called by muse, mutect2, varscan2
- SLC6A6 | c.1105C>T p.L369= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV62651538; called by muse, mutect2, varscan2
- SLCO3A1 | c.1311C>T p.S437= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100574879; called by muse, mutect2, varscan2
- SPEF2 | c.4485C>T p.I1495= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs750269898, COSV57431190; called by muse, mutect2, varscan2
- SPRY3 | c.114C>T p.A38= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs1457834434, COSV100249135; called by muse, mutect2, varscan2
- SRPRA | c.921T>C p.S307= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV55008150; called by muse, varscan2
- SRRM2 | c.5730A>G p.R1910= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV57078126; called by muse, mutect2, varscan2
- STAU1 | c.789T>C p.P263= (on ENST00000371856 / NM_001319135.1; = p.P182= on NM_004602.3) | Silent (SNP) | VAF 44/308 reads (14%) | catalogued as COSV61461708; called by muse, mutect2, varscan2
- STIL | c.3207G>T p.L1069= | Silent (SNP) | VAF 53/104 reads (51%) | catalogued as COSV54552341; called by muse, mutect2, varscan2
- SYK | c.1083G>A p.K361= | Silent (SNP) | VAF 67/177 reads (38%) | catalogued as rs771809467, COSV101002259, COSV65326378; called by muse, mutect2, varscan2
- SYNE1 | c.20820C>T p.S6940= (on ENST00000367255 / NM_182961.4; = p.S6869= on NM_033071.3) | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV99552288; called by muse, mutect2, varscan2
- TARBP2 | c.573A>G p.E191= (on ENST00000266987 / NM_134323.2; = p.E170= on NM_004178.4) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV57200323; called by muse, mutect2, varscan2
- TAS2R14 | c.540A>C p.V180= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV67860706; called by muse, mutect2, varscan2
- TATDN3 | c.435T>C p.N145= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV65325589; called by muse, mutect2, varscan2
- TCF20 | c.2136T>C p.S712= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as COSV59494515; called by muse, mutect2, varscan2
- TCF20 | c.1944T>C p.S648= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV59494523; called by muse, mutect2, varscan2
- TENM4 | c.4683G>A p.R1561= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1315163283, COSV53653765; called by muse, mutect2, varscan2
- TG | c.2433A>G p.E811= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV55088246; called by muse, varscan2
- TLR5 | c.219G>A p.Q73= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as rs148506161; called by muse, mutect2, varscan2
- TMEM245 | c.2338T>C p.L780= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV65823852; called by muse, mutect2, varscan2
- TMEM38B | c.66C>T p.D22= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs758077267, COSV65966758; called by muse, mutect2, varscan2
- TNK2 | c.2355C>T p.S785= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs768435264, COSV57370664; called by muse, mutect2, varscan2
- TNXB | c.7776G>A p.K2592= (on ENST00000647633; = p.K2345= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 125/386 reads (32%) | catalogued as COSV64485030; called by muse, mutect2, varscan2
- TOGARAM2 | c.1440G>A p.K480= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs769374826, COSV101091101, COSV65420590; called by muse, mutect2, varscan2
- TPM3 | c.30G>A p.Q10= | Silent (SNP) | VAF 66/84 reads (79%) | catalogued as COSV55138203; called by muse, mutect2, varscan2
- TRIM3 | c.1422C>T p.F474= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1350042667, COSV61984949; called by muse, mutect2, varscan2
- TRPM7 | c.4083C>T p.S1361= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV57919806; called by muse, mutect2, varscan2
- TTI1 | c.612T>C p.D204= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV65062722; called by muse, mutect2, varscan2
- TTLL4 | c.741C>T p.I247= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV51438352; called by muse, mutect2, varscan2
- TUT4 | c.1323A>G p.L441= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV57117727; called by muse, mutect2, varscan2
- UBA2 | c.1788T>C p.D596= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55829600; called by muse, mutect2, varscan2
- UGT2A1 | c.1452C>T p.F484= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as COSV54144968; called by muse, mutect2, varscan2
36 further variants in this file (0 protein-altering or splice-affecting, 17 silent, 19 other) are not listed here.
